Surgical pathology report (de-identified scan), TCGA case TCGA-F4-6808, project TCGA-COAD (Colon Adenocarcinoma), tissue source site Asterand, specimen TCGA-F4-6808-01A (Primary Tumor).

[page 1 of 2]
			Formatted Path Report	
		ID		
			LARGE INTESTINE TISSUE CHECKLIST	
			Specimen type: Excision of tumor	
			Specimen size: Not specified	
			Tumor site: Sigmoid colon	
			Tumor size: 3.5 x 3 x 3 cm	
			Tumor features: None specified	
			Histologic type: Adenocarcinoma	
			Histologic grade: Moderately differentiated	
			Tumor extent: Submucosa	
			Lymph nodes: 0/3 positive for metastasis (Regional 0/3)	
			Margins: Not specified	
			Evidence of neo-adjuvant treatment: Not specified	
			Additional pathologic findings: Not specified	
			Comments: None	

[page 2 of 2]
Date of Procurement

1. **Introduction**

2. **Background**

3. **Methodology**

4. **Results**

5. **Discussion**

6. **Conclusion**

7. **References**

8. **Appendix**

9. **Index**

10. **Table of Contents**

11. **Abstract**

12. **Summary**

13. **Key Words**

14. **Keywords**

15. **Keywords**

16. **Keywords**

17. **Keywords**

18. **Keywords**

19. **Keywords**

20. **Keywords**

21. **Keywords**

22. **Keywords**

23. **Keywords**

24. **Keywords**

25. **Keywords**

26. **Keywords**

27. **Keywords**

28. **Keywords**

29. **Keywords**

30. **Keywords**

31. **Keywords**

32. **Keywords**

33. **Keywords**

34. **Keywords**

35. **Keywords**

36. **Keywords**

37. **Keywords**

38. **Keywords**

39. **Keywords**

40. **Keywords**

41. **Keywords**

42. **Keywords**

43. **Keywords**

44. **Keywords**

45. **Keywords**

46. **Keywords**

47. **Keywords**

48. **Keywords**

49. **Keywords**

50. **Keywords**

51. **Keywords**

52. **Keywords**

53. **Keywords**

54. **Keywords**

55. **Keywords**

56. **Keywords**

57. **Keywords**

58. **Keywords**

59. **Keywords**

60. **Keywords**

61. **Keywords**

62. **Keywords**

63. **Keywords**

64. **Keywords**

65. **Keywords**

66. **Keywords**

67. **Keywords**

68. **Keywords**

69. **Keywords**

70. **Keywords**

71. **Keywords**

72. **Keywords**

73. **Keywords**

74. **Keywords**

75. **Keywords**

76. **Keywords**

77. **Keywords**

78. **Keywords**

79. **Keywords**

80. **Keywords**

81. **Keywords**

82. **Keywords**

83. **Keywords**

84. **Keywords**

85. **Keywords**

86. **Keywords**

87. **Keywords**

88. **Keywords**

89. **Keywords**

90. **Keywords**

91. **Keywords**

92. **Keywords**

93. **Keywords**

94. **Keywords**

95. **Keywords**

96. **Keywords**

97. **Keywords**

98. **Keywords**

99. **Keywords**

100. **Keywords**

101. **Keywords**

102. **Keywords**

103. **Keywords**

104. **Keywords**

105. **Keywords**

106. **Keywords**

107. **Keywords**

108. **Keywords**

109. **Keywords**

110. **Keywords**

111. **Keywords**

112. **Keywords**

113. **Keywords**

114. **Keywords**

115. **Keywords**

116. **Keywords**

117. **Keywords**

118. **Keywords**

119. **Keywords**

120. **Keywords**

121. **Keywords**

122. **Keywords**

123. **Keywords**

124. **Keywords**

125. **Keywords**

126. **Keywords**

127. **Keywords**

128. **Keywords**

129. **Keywords**

130. **Keywords**

131. **Keywords**

132. **Keywords**

133. **Keywords**

134. **Keywords**

135. **Keywords**

136. **Keywords**

137. **Keywords**

138. **Keywords**

139. **Keywords**

140. **Keywords**

141. **Keywords**

142. **Keywords**

143. **Keywords**

144. **Keywords**

145. **Keywords**

146. **Keywords**

147. **Keywords**

148. **Keywords**

149. **Keywords**

150. **Keywords**

151. **Keywords**

152. **Keywords**

153. **Keywords**

154. **Keywords**

155. **Keywords**

156. **Keywords**

157. **Keywords**

158. **Keywords**

159. **Keywords**

160. **Keywords**

161. **Keywords**

162. **Keywords**

163. **Keywords**

164. **Keywords**

165. **Keywords**

166. **Keywords**

167. **Keywords**

168. **Keywords**

169. **Keywords**

170. **Keywords**

171. **Keywords**

172. **Keywords**

173. **Keywords**

174. **Keywords**

175. **Keywords**

176. **Keywords**

177. **Keywords**

178. **Keywords**

179. **Keywords**

180. **Keywords**

181. **Keywords**

182. **Keywords**

183. **Keywords**

184. **Keywords**

185. **Keywords**

186. **Keywords**

187. **Keywords**

188. **Keywords**

189. **Keywords**

190. **Keywords**

191. **Keywords**

192. **Keywords**

193. **Keywords**

194. **Keywords**

195. **Keywords**

196. **Keywords**

197. **Keywords**

198. **Keywords**

199. **Keywords**

200. **Keywords**

201. **Keywords**

202. **Keywords**

203. **Keywords**

204. **Keywords**

205. **Keywords**

206. **Keywords**

207. **Keywords**

208. **Keywords**

209. **Keywords**

210. **Keywords**

211. **Keywords**

212. **Keywords**

213. **Keywords**

214. **Keywords**

215. **Keywords**

216. **Keywords**

217. **Keywords**

218. **Keywords**

219. **Keywords**

220. **Keywords**

221. **Keywords**

222. **Keywords**

223. **Keywords**

224. **Keywords**

225. **Keywords**

226. **Keywords**

227. **Keywords**

228. **Keywords**

229. **Keywords**

230. **Keywords**

231. **Keywords**

232. **Keywords**

233. **Keywords**

234. **Keywords**

235. **Keywords**

236. **Keywords**

237. **Keywords**

238. **Keywords**

239. **Keywords**

240. **Keywords**

241. **Keywords**

242. **Keywords**

243. **Keywords**

244. **Keywords**

245. **Keywords**

246. **Keywords**

247. **Keywords**

248. **Keywords**

249. **Keywords**

250. **Keywords**

251. **Keywords**

252. **Keywords**

253. **Keywords**

254. **Keywords**

255. **Keywords**

256. **Keywords**

257. **Keywords**

258. **Keywords**

259. **Keywords**

260. **Keywords**

261. **Keywords**

262. **Keywords**

263. **Keywords**

264. **Keywords**

265. **Keywords**

266. **Keywords**

267. **Keywords**

268. **Keywords**

269. **Keywords**

270. **Keywords**

271. **Keywords**

272. **Keywords**

273. **Keywords**

274. **Keywords**

275. **Keywords**

276. **Keywords**

277. **Keywords**

278. **Keywords**

2

Source: NCI Genomic Data Commons file fd383e4d-dfb4-4203-a456-4dcc816af448 (TCGA-F4-6808.02919AA1-8F7B-499C-A799-C09984AF58E0.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).